Gene-level copy-number profile of tumor specimen TCGA-B6-A0X1-01A from TCGA case TCGA-B6-A0X1, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 48.3 years (17,624 days).
Specimen TCGA-B6-A0X1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.66665c22-d495-4ae1-a6fe-378d96c05c1a.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0X1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 394 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ddb2f7da-9492-4204-8334-684fd18c738d

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 574; copy number 1: 31,701; copy number 2: 22,729; copy number 3: 3,884; copy number 4: 1,326; copy number 5: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A0X1-01A-11D-A107-01): tumor purity 0.74, ploidy 1.52, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:227,472,132–229,714,555, 35 genes: MIR5703, AGFG1, SCYGR9, SCYGR2, SCYGR10, C2orf83, SCYGR3, AC064853.1, SCYGR4, SCYGR5, SLC19A3, SCYGR6, SCYGR7, SCYGR8, RNA5SP121, SNRPGP8, AC073065.1, CCL20, TDGF1P2, DAW1, AC073065.2, SPHKAP, RNU6-624P, SNF8P1, AC009410.1, LINC01807, AC012070.1, RPL7L1P10, PID1, RPL17P14, RN7SKP283, DNER, AC008273.1, RNU7-9P, AC007559.1.
- chr4:5,542,772–5,709,548, 1 gene: EVC2.
- chr4:114,598,770–114,799,629, 4 genes (within-gene range 0–1): UGT8, MIR577, CIR1P2, RN7SL808P.
- chr5:56,260,333–56,606,232, 10 genes: RNA5SP185, PSMC1P4, RNU6ATAC2P, AC034245.1, HMGN1P17, LINC01948, AC008391.1, RPL26P19, C5orf67, AC022431.1.
- chr16:84,368,527–84,467,361, 2 genes (within-gene range 0–1): ATP2C2, ATP2C2-AS1.
- chr16:84,495,599–84,497,495, 1 gene: AC022165.1.
- chr18:8,360,820–8,367,034, 1 gene: AP001094.3.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 5,075 genes in 99 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,600,172–33,321,098, 27 genes, copy number 4 (within-gene range 2–4): ZBTB8OS, Y_RNA, RBBP4, SYNC, AC114489.1, KIAA1522, YARS1, S100PBP, FNDC5, HPCA, TMEM54, AL031602.2, RNF19B, AL031602.1, AL355864.1, AL355864.2, AL020995.1, AK2, Metazoa_SRP, AZIN2, AL662907.1, TRIM62, AL662907.2, AL662907.3, ZNF362, AL513327.2, A3GALT2.
- chr1:46,843,095–47,550,753, 26 genes, copy number 3: CYP4Z2P, TUBAP8, CYP4A11, CYP4A26P, CYP4A43P, CYP4A27P, CYP4A44P, CYP4X1, CYP4Z1, TUBAP9, CYP4A22-AS1, CYP4A22, MTND1P34, LINC00853, PDZK1IP1, TAL1, AL135960.1, STIL, CMPK1, LINC01389, FOXE3, FOXD2-AS1, FOXD2, AL356458.1, RPL21P24, ATP6V0E1P4.
- chr1:52,842,511–62,688,386, 179 genes, copy number 3–5 (within-gene range 2–5) (broad region; genes not listed).
- chr1:64,745,095–65,714,847, 23 genes, copy number 3: RAVER2, JAK1, AL606517.2, AL606517.1, LINC01359, SLC2A3P2, AL357078.2, RNU6-1176P, MIR3671, MIR101-1, AL357078.1, MRPS21P1, AK4, RPS29P7, DNAJC6, AL139294.1, COX6CP13, RNU2-15P, LEPROT, LEPR, AC119800.1, AC097063.1, AL513493.1.
- chr1:77,562,416–78,138,444, 18 genes, copy number 3–4 (within-gene range 1–4): ZZZ3, RNA5SP20, RN7SL370P, USP33, ACTG1P21, MIGA1, RNA5SP21, AC138392.1, NSRP1P1, HSPE1P25, NEXN-AS1, NEXN, FUBP1, DNAJB4, GIPC2, AC103591.3, AC103591.4, AC103591.2.
- chr1:200,253,419–201,429,866, 30 genes, copy number 3: LINC00862, AC097065.2, AC097065.1, AC104461.1, ZNF281, AL359834.1, KIF14, DDX59, DDX59-AS1, CAMSAP2, RPL34P6, GPR25, INAVA, MROH3P, RNU6-704P, KIF21B, AL358473.1, AL358473.2, CACNA1S, ASCL5, TMEM9, IGFN1, AC103925.1, PKP1, TNNT2, AC119427.2, LAD1, AC119427.1, TNNI1, AC096677.3.
- chr1:209,267,798–209,857,565, 18 genes, copy number 3: ATP5MC2P1, LINC01696, LINC01698, MIR205HG, MIR205, AL023754.1, AL023754.2, CAMK1G, LAMB3, MIR4260, HSD11B1-AS1, G0S2, HSD11B1, ADORA2BP1, TRAF3IP3, C1orf74, IRF6, UTP25.
- chr1:224,107,282–224,437,033, 14 genes, copy number 3: RN7SKP49, FBXO28, AC092809.3, DEGS1, SNORA72, AC092809.2, AC092809.4, NVL, MIR320B2, AC092809.1, RNU6-1008P, CNIH4, WDR26, MIR4742.
- chr2:37,816,915–38,603,586, 21 genes, copy number 3: AC010878.1, LINC00211, RMDN2, RMDN2-AS1, CYP1B1, CYP1B1-AS1, AC009229.4, AC009229.2, RNU6-951P, AC009229.3, AC009229.1, RPL7P12, GAPDHP25, ATL2, LINC02613, AC016995.1, LINC01883, RPLP0P6, AC011247.2, HNRNPLL, AC011247.1.
- chr2:85,460,144–96,377,091, 302 genes, copy number 3 (broad region; genes not listed).
- chr2:182,716,041–183,495,501, 15 genes, copy number 3 (within-gene range 2–3): DNAJC10, RPL31P15, Y_RNA, FRZB, RNU6-1122P, NCKAP1, Y_RNA, AC064871.1, KRT8P10, DUSP19, AC064871.2, NUP35, AC021851.1, AC021851.2, LIN28AP1.
- chr2:189,560,590–190,203,484, 16 genes, copy number 3 (within-gene range 2–3): SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1, C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN.
- chr2:192,629,919–195,572,970, 26 genes, copy number 3: AC062039.1, AC013401.1, PCGEM1, RPS17P8, AC013401.2, AC096647.1, SLC44A3P1, DNAJC17P1, SEC61GP1, AC074290.1, AC068135.2, AC068135.1, GLULP6, HNRNPA1P47, LINC01821, AC106883.1, AC073973.1, Metazoa_SRP, AC006196.1, LINC01790, AC010983.1, AC104823.1, AC064834.1, RNU6-169P, LINC01825, LINC01827.
- chr3:158,545,189–158,871,821, 15 genes, copy number 3: AC106707.1, MLF1, MTAPP1, AC025033.1, GFM1, LXN, AC080013.3, RARRES1, MFSD1, AC080013.1, RPL35AP9, AC080013.2, AC080013.4, GPR79, AC092999.1.
- chr3:160,225,496–160,697,060, 16 genes, copy number 3: C3orf80, AC079594.1, IFT80, RPL35AP10, SMC4, MIR15B, MIR16-2, TRIM59, B3GAT3P1, RNU7-136P, KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72.
- chr4:53,986,587–54,740,715, 15 genes, copy number 3 (within-gene range 1–3): RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT.
- chr5:659,862–1,178,605, 18 genes, copy number 3: TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3.
- chr5:8,080,186–16,941,951, 136 genes, copy number 3–4 (broad region; genes not listed).
- chr5:181,147,586–181,342,213, 23 genes, copy number 3: OR2V2, LINC01962, AC008443.4, TRIM7, TRIM7-AS1, AC008443.3, AC008443.7, TRIM41, MIR4638, AC008443.1, RACK1, SNORD96A, SNORD95, CTC-338M12.4, TRIM52, TRIM52-AS1, AC008443.6, AC008443.2, AC008443.5, RNU6-705P, AC138035.1, AC138035.3, AC138035.2.
- chr6:53,647,916–54,625,488, 15 genes, copy number 3: KLHL31, AL590652.1, LRRC1, AL033384.2, MLIP, AL033384.1, MLIP-AS1, MLIP-IT1, ERHP2, AL359380.1, TINAG, TINAG-AS1, CLNS1AP1, RPL10P10, RPSAP44.
- chr7:57,402,181–62,275,678, 30 genes, copy number 3: AC237221.2, AC237221.1, MIR3147, VN1R28P, SAPCD2P2, ZNF716, AC092175.1, NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13, AC128676.1.
- chr7:111,726,110–159,233,377, 959 genes, copy number 3–5 (broad region; genes not listed).
- chr8:6,406,596–6,938,306, 18 genes, copy number 3 (within-gene range 2–3): MCPH1, AC016065.2, ANGPT2, AC018398.2, AF287957.1, MCPH1-AS1, MIR8055, AGPAT5, MIR4659A, MIR4659B, AF233439.2, XKR5, GS1-24F4.2, DEFB1, RPL23AP96, DEFA6, AF233439.1, DEFA4.
- chr8:101,847,256–145,066,685, 653 genes, copy number 3–5 (within-gene range 3–6) (broad region; genes not listed).
- chr9:32,293,558–33,039,907, 23 genes, copy number 3: RNA5SP281, SLC25A5P8, ACO1, DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1, TAF1L, AL589642.1, AL589642.2, SNRPCP1, AL157884.1, TMEM215, Y_RNA, AL157884.3, AL157884.2, APTX, BOLA3P4, ASS1P12, TCEA1P4, LAGE3P1, DNAJA1.
- chr9:60,914,407–91,001,901, 476 genes, copy number 3 (broad region; genes not listed).
- chr10:27,378,138–28,334,486, 15 genes, copy number 3 (within-gene range 2–3): TRIAP1P1, PTCHD3, RAB18, LINC02680, MKX, MKX-AS1, ARMC4, RN7SKP132, RPL36AP55, AL390866.1, MRPS21P5, MPP7, AL355501.1, MIR8086, MPP7-DT.
- chr11:33,665,220–35,020,591, 31 genes, copy number 3–4 (within-gene range 2–4): AL049629.1, C11orf91, AL049629.2, CD59, FBXO3, FBXO3-DT, AC113192.3, AC113192.2, LINC02722, AC113192.1, LINC02721, LMO2, AC132216.1, AC090469.1, CAPRIN1, NAT10, ABTB2, Y_RNA, MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343.
- chr11:55,786,964–56,703,884, 77 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr11:57,576,292–58,731,974, 59 genes, copy number 3 (within-gene range 2–3): RPS4XP13, SERPING1, AP000662.1, MIR130A, YPEL4, CLP1, ZDHHC5, MED19, AP001931.2, TMX2, PPIAP42, SELENOH, AP001931.1, BTBD18, CTNND1, OR5BA1P, AP003484.1, OR5AZ1P, OR5BD1P, CYCSP26, OR9Q1, RNU6-899P, OR6Q1, VN2R9P, AP004247.2, AP004247.1, OR9L1P, OR9I3P, OR9I1, OR9I2P, OR5BL1P, OR9Q2, OR1S2, OR1S1, OR10Q1, EIF4A2P3, OR10W1, OR10Q2P, OR5BC1P, OR5B19P, OR5B10P, AP000435.1, OR5B17, OR5B1P, OR5B15P, OR5B3, OR5B2, OR5B12, AP003557.2, AP003557.1, OR5B21, LPXN, ZFP91, ZFP91-CNTF, AP001350.1, CNTF, AP001350.2, GLYAT, AP000445.1.
- chr11:68,870,664–82,718,299, 348 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr12:66,767–11,171,608, 406 genes, copy number 4 (within-gene range 2–4) (broad region; genes not listed).
- chr12:20,014,780–25,209,645, 71 genes, copy number 4–5 (within-gene range 2–6) (broad region; genes not listed).
- chr16:10,840,384–11,916,082, 39 genes, copy number 3 (within-gene range 2–3): AC133065.2, AC133065.1, CIITA, DEXI, AC133065.3, CLEC16A, RPL7P46, AC007014.2, AC007014.1, AC007220.2, AC007220.1, HNRNPCP4, RMI2, SOCS1, TNP2, PRM3, AC009121.1, PRM2, PRM1, AC009121.4, MIR548H2, Y_RNA, AC009121.3, AC009121.2, AC099489.1, AC099489.2, AC099489.3, LITAF, SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4, RSL1D1, AC007216.4, GSPT1, AC007216.3.
- chr16:25,015,978–26,137,685, 24 genes, copy number 3 (within-gene range 2–7): AC133552.1, AC133552.2, LINC02175, SCML2P2, AC133552.4, LCMT1-AS1, AC133552.3, AC133552.5, LCMT1, LCMT1-AS2, RN7SL557P, AQP8, ZKSCAN2, AC008741.1, ZKSCAN2-DT, LINC02191, CYCSP39, HS3ST4, AC093516.1, AC093524.1, MIR548W, RNA5SP405, HMGN2P3, HSPE1P16.
- chr18:56,137,573–80,247,514, 362 genes, copy number 3 (broad region; genes not listed).
- chr19:34,837,889–35,625,355, 58 genes, copy number 3 (within-gene range 2–3): AC008555.2, AC008555.4, AC008555.3, LINC00904, LINC01838, ZNF30-AS1, ZNF30, AC008555.6, ZNF792, GRAMD1A, AC020907.3, AC020907.4, SCN1B, HPN, HPN-AS1, AC020907.1, AC020907.6, FXYD3, MIR6887, LGI4, AC020907.5, FXYD1, AC020907.2, FXYD7, FXYD5, FAM187B, FAM187B2P, LSR, AC002128.2, AC002128.1, USF2, HAMP, MAG, CD22, U62631.1, MIR5196, FFAR1, FFAR3, GPR42, EEF1A1P7, LINC01531, AC002511.3, RN7SL491P, AC002511.2, AC002511.1, FFAR2, KRTDAP, DMKN, SBSN, GAPDHS, TMEM147-AS1, TMEM147, ATP4A, AD000090.1, PMIS2, LINC01766, AC002115.1, HAUS5.
- chr19:38,108,500–38,975,742, 50 genes, copy number 3 (within-gene range 2–3): AC011465.1, AC011479.3, AC011479.2, RN7SL663P, DPF1, SPINT2, PPP1R14A, AC011479.1, AC011479.4, Y_RNA, YIF1B, C19orf33, KCNK6, CATSPERG, AC005625.1, PSMD8, GGN, AC005789.1, SPRED3, FAM98C, RASGRP4, RYR1, AC067969.2, AC067969.1, MAP4K1, AC008649.1, EIF3K, ACTN4, AC008649.2, CAPN12, AC022144.1, LGALS7, LGALS7B, RNU6-140P, LGALS4, ECH1, AC008982.1, AC104534.1, HNRNPL, AC008982.2, RINL, AC011455.1, SIRT2, NFKBIB, CCER2, SARS2, AC011455.2, MRPS12, ERVK9-11, FBXO17.
- chr19:40,319,536–41,640,602, 82 genes, copy number 3 (broad region; genes not listed).
- chr22:35,298,838–36,179,385, 31 genes, copy number 3: AL008635.1, TOM1, MIR3909, MIR6069, Z82244.2, Z82244.1, HMOX1, MCM5, AL022334.1, AL022334.2, RASD2, MB, AL049747.1, APOL6, AL049748.1, MRPS16P3, APOL5, RBFOX2, NDUFA9P1, Z82217.1, Z95114.4, Z95114.1, Z95114.2, Z95114.3, APOL3, MTCO1P20, MTCO2P20, MTATP6P20, MTCO3P20, MTCYBP34, MTND1P10.

Autosomal genes at a single copy (total copy number 1): 31,695. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
